Gene-level copy-number profile of tumor specimen TCGA-ZJ-AB0I-01A from TCGA case TCGA-ZJ-AB0I, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Age at diagnosis: 26.0 years (9,486 days).
Specimen TCGA-ZJ-AB0I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.2486daf3-65de-4ecb-a87a-2876f3357b73.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZJ-AB0I-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3341cc04-fa90-4927-a3b3-8b95a38d17a2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 7,002; copy number 2: 38,479; copy number 3: 12,055; copy number 4: 2,175; copy number 5: 2; copy number 6: 90; copy number 7: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZJ-AB0I-01A-11D-A42N-01): tumor purity 0.9, ploidy 2.14, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:168,863,770–169,270,956, 7 genes (within-gene range 0–1): CBR4, RNU6-853P, RNY4P17, AC021151.1, SH3RF1, RPL6P12, AC096741.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 97 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,930,796–159,705,607, 26 genes, copy number 6: PYHIN1, IFI16, AIM2, RAD1P2, CADM3, RNA5SP60, CADM3-AS1, ACKR1, MPTX1, OR10J2P, FCER1A, OR10J3, AL513323.1, OR10J7P, OR10J8P, OR10J9P, OR10J4, OR10J1, LINC02819, OR10J5, AL606752.1, OR10AE1P, APCS, OR10J6P, AL445528.2, CRPP1.
- chr3:75,906,695–77,649,964, 1 gene, copy number 5 (within-gene range 1–7): ROBO2.
- chr3:77,092,057–78,092,270, 6 genes, copy number 5–7: RNU6-386P, VDAC1P7, AC133040.1, RNU6-217P, LINC02077, AC117462.1.
- chr5:19,471,296–26,013,025, 63 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:17,922,840–18,027,975, 1 gene, copy number 6 (within-gene range 2–6): PCM1.

Autosomal genes at a single copy (total copy number 1): 7,001. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
